CCDI case PBBNZV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4fa92631-42d7-42bd-ab3f-4cce7b08791c

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.3 years (3,767 days).

Biospecimens (3 samples)
- Sample 0DFF6Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFF75: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DFF77: Tissue type: Tumor; Specimen type: Solid Tissue.
